Gene-level copy-number profile of tumor specimen ALCH-B2AS-TTP1-A from ALCHEMIST case ALCH-B2AS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 53.8 years (19,667 days).
Specimen ALCH-B2AS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1473e58c-2199-4e82-baaa-b9b87187ac60.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2AS-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/205d291f-4937-48aa-befc-68dea8c2bd0e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 5,890; copy number 2: 50,288; copy number 3: 2,602; copy number 4: 85; copy number 5: 21; copy number 6: 3; copy number 7: 2.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:155,962,632–155,966,343, 1 gene: AC021218.1.
- chr11:65,857,126–65,873,592, 2 genes (within-gene range 0–3): MUS81, EFEMP2.
- chr11:66,016,752–66,026,479, 1 gene: CATSPER1.
- chr12:108,129,288–108,250,537, 1 gene (within-gene range 0–1): WSCD2.
- chr13:111,588,201–112,052,138, 4 genes: AL359649.1, LINC02337, LINC00354, AL138691.1.
- chr13:112,067,149–112,071,706, 1 gene: SOX1.
- chr17:6,393,693–6,435,199, 2 genes: AIPL1, AC055872.1.
- chr17:34,579,487–34,726,170, 3 genes: TMEM132E, AC005691.1, AC005552.1.
- chr17:46,259,551–46,260,606, 1 gene: AC005829.2.
- chr22:49,213,911–49,214,247, 1 gene: RPL35P8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 26 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:171,815,586–172,604,006, 14 genes, copy number 5: TMEM212-AS1, TMEM212, TMEM212-IT1, AC055714.1, FNDC3B, RPS27AP8, RN7SL141P, AC092964.1, BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1.
- chr8:38,382,364–38,383,461, 1 gene, copy number 5: AC087623.2.
- chr11:65,367,438–65,383,701, 2 genes, copy number 5: AP000944.1, SLC25A45.
- chr11:65,423,273–65,424,118, 3 genes, copy number 6: AP000944.4, AP000944.3, AP000944.2.
- chr11:66,012,008–66,013,505, 1 gene, copy number 5: CST6.
- chr17:46,292,733–46,337,794, 2 genes, copy number 7 (within-gene range 2–7): LRRC37A, RN7SL656P.
- chr17:50,944,104–50,948,750, 1 gene, copy number 5 (within-gene range 2–5): AC005920.3.
- chr19:1,103,926–1,106,791, 1 gene, copy number 5: GPX4.
- chr20:50,479,767–50,479,991, 1 gene, copy number 5: COX6CP2.

Autosomal genes at a single copy (total copy number 1): 3,034. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
